MMRF case MMRF_1893 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/e3202caf-9076-48de-8fa3-437e545a6bda

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 38 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 38.5 years (14,050 days); ISS stage: I; Days to last known disease status: 1,016 days (2.8 years); Days to last follow up: 1,016 days (2.8 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 3 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 4 days; Days to treatment end: 73 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 120 days; Days to treatment end: 120 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 232 days; Days to treatment end: 802 days (2.2 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 1): M Protein 1.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 27.6 mg/dL; Immunoglobulin G 19.8 g/L; Immunoglobulin A 0.263 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 2.8 µg/mL; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 8.4 g/dL; Glucose 5.67 mmol/L.
- Day 57 (ECOG 1): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.35 mg/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 3.57 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 10.2 ×10⁹/L; Absolute Neutrophil 8.16 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 9.74 mmol/L.
- Day 144 (ECOG 1): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.8 mg/dL; Immunoglobulin G 12.8 g/L; Immunoglobulin A 1.48 g/L; Immunoglobulin M 0.515 g/L; Lactate Dehydrogenase 4.33 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 115 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL; Glucose 6.49 mmol/L.
- Day 252 (ECOG 0): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.8 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 0.298 g/L; Immunoglobulin M 0.19 g/L; Hemoglobin 8.99 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.99 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.35 mmol/L; Total Protein 6.6 g/dL; Glucose 6.71 mmol/L.
- Day 316: Hemoglobin 8.31 mmol/L; Leukocytes 4.19 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Total Protein 6.8 g/dL; Glucose 4.95 mmol/L.
- Day 414: M Protein 0.38 g/dL; Immunoglobulin G 8.38 g/L; Hemoglobin 8.93 mmol/L; Leukocytes 4.47 ×10⁹/L; Absolute Neutrophil 2.81 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL; Glucose 5.67 mmol/L.
- Day 505: M Protein 0.29 g/dL; Immunoglobulin G 7.43 g/L; Hemoglobin 9.11 mmol/L; Leukocytes 4.52 ×10⁹/L; Absolute Neutrophil 2.48 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.1 mmol/L; Total Protein 6.3 g/dL; Glucose 6.05 mmol/L.
- Day 589: Hemoglobin 9.18 mmol/L; Leukocytes 4.49 ×10⁹/L; Absolute Neutrophil 2.36 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.05 mmol/L; Total Protein 6.4 g/dL; Glucose 5.61 mmol/L.
- Day 680: M Protein 0.32 g/dL; Immunoglobulin G 7.4 g/L.
- Day 773: M Protein 0.34 g/dL; Immunoglobulin G 7.92 g/L.
- Day 878 (ECOG 0): M Protein 0.35 g/dL; Immunoglobulin G 7.63 g/L; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 9.42 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.68 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.25 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 7.43 mmol/L.
- Day 1,016 (ECOG 0): Hemoglobin 9.3 mmol/L; Leukocytes 7.06 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 5.94 mmol/L.

Other clinical attributes
- Day -6: Weight: 89 kg; Height: 170 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1893_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_1893_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
